Somatic mutation profile of tumor specimen MMRF_1540_1_BM_CD138pos (aliquot MMRF_1540_1_BM_CD138pos_T1_KBS5U_L03506) from MMRF case MMRF_1540, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.3 years (21,287 days).
Specimen MMRF_1540_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce88f09f-50ee-424a-94ca-33fe4600f330.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1540_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1540_1_PB_CD3pos_C2_KBS5U_L03510; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb34ac6f-4d8b-4cfc-b2e6-74e0873acc6a

The open-access MAF lists 91 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 30, Silent 10, Intron 6, Splice Site 3, 5'UTR 3, RNA 2, 3'Flank 2, 5'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHST15 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs377640808; called by muse, varscan2
- GMPR | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs747618542, COSV52475095; called by muse, mutect2, varscan2
- HDAC7 | c.1347G>C p.L449F (on ENST00000427332; = p.L488F on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1324407095; called by muse, mutect2, varscan2
- IGHV4-39 | c.40T>G p.F14V | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs587738503; called by muse, varscan2
- IGLV3-25 | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs779596451; called by muse, varscan2
- KREMEN2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.411); catalogued as COSV53556944; called by muse, mutect2
- LAMA3 | c.5462-1G>T p.X1821_splice (on ENST00000313654 / NM_198129.4; = p.X212_splice on NM_000227.6) | Splice Site (SNP) | VAF 26/60 reads (43%) | catalogued as CS1414652; called by muse, mutect2, varscan2
- SLC7A11 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs373200291; called by mutect2, varscan2
- TRERF1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs534220721, COSV61668722; called by muse, mutect2, varscan2
- ABCC3 | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ARHGAP4 | c.2045A>T p.Q682L | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2
- CACNA1B | c.1717G>T p.G573W | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1B | c.1718G>T p.G573V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP295 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); called by muse, mutect2
- COL13A1 | c.1882-1G>T p.X628_splice (on ENST00000398978 / NM_001130103.2; = p.X556_splice on NM_080798.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- CSMD3 | c.3496T>C p.S1166P (on ENST00000297405 / NM_001363185.1; = p.S1062P on NM_052900.3) | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DOCK9 | c.5530G>A p.V1844I (on ENST00000376460 / NM_001366676.2; = p.V1845I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 106/248 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- FMO3 | c.1337A>T p.N446I | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GPI | c.431A>T p.Y144F | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GRK1 | c.1446G>T p.K482N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HUWE1 | c.2261+2T>A p.X754_splice | Splice Site (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- MAGI1 | c.1101G>C p.K367N | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- NR2F2 | c.161A>G p.Q54R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NUTF2 | c.127G>C p.G43R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- OR4D11 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PCDHB9 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM13 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RASGRP3 | c.12_24del p.S4Rfs*5 | Frame Shift Del (DEL) | VAF 54/368 reads (15%) | called by mutect2, varscan2
- SEMA3F | c.282G>T p.W94C | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SP6 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2
- TG | c.3094G>A p.D1032N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.136); called by muse, mutect2
- TGFA | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM11 | c.80C>A p.T27K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TP73 | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, varscan2
- AKNA | c.1287A>T p.V429= | Silent (SNP) | VAF 51/113 reads (45%) | called by muse, mutect2, varscan2
- C2orf76 | c.192A>G p.L64= | Silent (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- CCDC57 | c.606C>T p.S202= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- DACH2 | c.264G>C p.L88= | Silent (SNP) | VAF 63/135 reads (47%) | called by muse, mutect2, varscan2
- IGLL5 | c.322C>T p.L108= | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as rs373280795, COSV66537663; called by muse, varscan2
- LAMB4 | c.1962A>G p.L654= | Silent (SNP) | VAF 14/66 reads (21%) | called by mutect2, varscan2
- MTTP | c.2376G>C p.V792= | Silent (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- NBEA | c.4716G>A p.S1572= | Silent (SNP) | VAF 29/133 reads (22%) | catalogued as COSV59791410; called by muse, mutect2, varscan2
- PIK3CG | c.2454C>T p.A818= | Silent (SNP) | VAF 30/268 reads (11%) | catalogued as rs763798647, COSV63247956; called by muse, mutect2, varscan2
- SIPA1L2 | c.2472C>A p.T824= | Silent (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- AC124067.4 | n.1601G>C | RNA (SNP) | VAF 59/111 reads (53%) | called by muse, mutect2, varscan2
- ADARB1 | c.*3866C>A | 3'UTR (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- ADARB1 | c.*3867T>G | 3'UTR (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- AMBP | c.*44C>A | 3'UTR (SNP) | VAF 82/174 reads (47%) | catalogued as COSV99468876; called by muse, mutect2, varscan2
- AP2A2 | c.2296+504C>G | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- CDON | c.*511C>A | 3'UTR (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- CLVS1 | c.*216G>A | 3'UTR (SNP) | VAF 60/108 reads (56%) | called by muse, mutect2
- COL6A5 | c.*392T>C | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11930C>T | Intron (SNP) | VAF 52/131 reads (40%) | catalogued as rs1410414144; called by muse, mutect2, varscan2
- DIAPH2 | c.*2241T>G | 3'UTR (SNP) | VAF 53/121 reads (44%) | called by muse, mutect2, varscan2
- F8 | c.-120del | 5'UTR (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- FAM107B | chr10:14519055 T>G | 3'Flank (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- FAM199X | c.*187G>C | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- FICD | c.*1614A>G | 3'UTR (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- FNDC3A | c.*13A>T | 3'UTR (SNP) | VAF 33/114 reads (29%) | called by muse, varscan2
- FOXF1 | c.*254T>G | 3'UTR (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- GALR2 | c.*53G>A | 3'UTR (SNP) | VAF 9/240 reads (4%) | called by muse, mutect2
- IBA57 | c.*5456A>T | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- IGF2 | chr11:2130904 C>T | 3'Flank (SNP) | VAF 12/50 reads (24%) | catalogued as rs1170567749; called by mutect2, varscan2
- INSIG1 | c.*614T>C | 3'UTR (SNP) | VAF 51/113 reads (45%) | called by muse, mutect2, varscan2
- KHDC4 | c.1646-41T>G | Intron (SNP) | VAF 33/132 reads (25%) | catalogued as rs766013862; called by mutect2, varscan2
- KRT80 | c.*1237G>T | 3'UTR (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- LETM2 | c.502-310G>T | Intron (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- LPXN | chr11:58578009 A>G | 5'Flank (SNP) | VAF 57/102 reads (56%) | called by muse, mutect2, varscan2
- LRAT | c.*1803C>A | 3'UTR (SNP) | VAF 64/131 reads (49%) | called by muse, mutect2, varscan2
- NAP1L3 | c.-134C>G | 5'UTR (SNP) | VAF 25/84 reads (30%) | catalogued as rs566146584; called by muse, mutect2, varscan2
- NFIB | c.*4248G>T | 3'UTR (SNP) | VAF 41/71 reads (58%) | called by muse, mutect2, varscan2
- NOS1 | c.*5708del | 3'UTR (DEL) | VAF 54/112 reads (48%) | called by mutect2, varscan2
- NRCAM | c.*1482C>A | 3'UTR (SNP) | VAF 48/105 reads (46%) | called by muse, mutect2, varscan2
- NUAK1 | c.*1719A>G | 3'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- NUDT13 | c.*327G>A | 3'UTR (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- PABPC3 | c.-108G>A | 5'UTR (SNP) | VAF 19/50 reads (38%) | catalogued as rs1381130001; called by muse, mutect2, varscan2
- PAPPA | c.*4555T>C | 3'UTR (SNP) | VAF 53/90 reads (59%) | called by muse, mutect2, varscan2
- PI4KA | chr22:20858812 G>T | 5'Flank (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- PPM1A | c.*5409C>T | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- PRPF40A | c.*4300C>T | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- PURA | c.*724T>C | 3'UTR (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- SAPCD2 | c.*197dup | 3'UTR (INS) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- SHE | c.*3107T>A | 3'UTR (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- SNX19 | c.*1696C>T | 3'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- SP4 | c.*2905G>A | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- SRRM2 | c.7734-310C>G | Intron (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
- STAC | c.*278G>A | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- SYBU | c.*333T>G | 3'UTR (SNP) | VAF 75/155 reads (48%) | called by muse, mutect2, varscan2
- TLL2 | c.2662+69C>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- TMEM47 | c.*2171C>G | 3'UTR (SNP) | VAF 39/71 reads (55%) | catalogued as rs1338001671; called by muse, mutect2, varscan2
- ZNF503-AS2 | n.740G>A | RNA (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
